Somatic mutation profile of tumor specimen MMRF_1361_3_BM_CD138pos (aliquot MMRF_1361_3_BM_CD138pos_T1_KBS5U_L05367) from MMRF case MMRF_1361, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,610 days).
Specimen MMRF_1361_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa5d7a56-7e09-4307-8061-01f9b58fbdb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1361_2_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1361_2_PB_CD3pos_C1_KAS5U_L01930; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea1943fb-43a2-4047-a8fe-e61f19e3b3a5

The open-access MAF lists 86 somatic variants for this specimen: 32 protein-altering or splice-affecting, 5 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 26, Missense Mutation 26, Intron 14, Silent 5, RNA 4, Frame Shift Del 3, 3'Flank 2, 5'UTR 2, 5'Flank 1, In Frame Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 20/44 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 5/64 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2
- BMI1 | c.317-3T>C | Splice Region (SNP) | VAF 11/28 reads (39%) | catalogued as rs1422079023, COSV64959144; called by muse, mutect2, varscan2
- CXorf58 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs761720174, COSV64858330; called by muse, mutect2, varscan2
- FAM47B | c.533A>C p.E178A | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100264658; called by muse, mutect2, varscan2
- GPR152 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as rs778997675, COSV56885395; called by muse, mutect2, varscan2
- HK2 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99308935; called by muse, mutect2
- IGLV3-25 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as rs376421895; called by muse, varscan2
- PHF20 | c.2258T>C p.I753T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.644); catalogued as rs376078655; called by muse, mutect2, varscan2
- PHRF1 | c.2509G>A p.G837S (on ENST00000264555 / NM_001286581.2; = p.G836S on NM_020901.4) | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199793786; called by muse, mutect2, varscan2
- PKHD1 | c.4601G>C p.S1534T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100584911, COSV61895893; called by muse, varscan2
- RCBTB2 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1052692658; called by muse, mutect2
- SI | c.4155G>T p.K1385N | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs760213744; called by muse, mutect2, varscan2
- SMARCA4 | c.2917C>G p.R973G | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV60787034; called by muse, mutect2
- ASB2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL1 | c.1933G>A p.G645S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOD1L1 | c.3472A>G p.T1158A | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- BTBD8 | c.1801del p.T601Lfs*2 (on ENST00000636805 / NM_001376131.1; = p.T88Lfs*2 on NM_015237.4) | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- CD2AP | c.1683del p.A562Lfs*3 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | called by pindel, varscan2
- CIP2A | c.103G>C p.V35L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.382); called by muse, mutect2
- ESR2 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (0.3); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- GPR19 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCT | c.2543T>C p.L848P | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- NLRP13 | c.2265del p.C755* | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- POT1 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); called by muse, mutect2
- REEP4 | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.297); called by muse, mutect2
- RYR2 | c.4216A>C p.T1406P | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SLC5A12 | c.1629T>A p.C543* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- TASOR | c.4775C>T p.P1592L (on ENST00000355628 / NM_001365636.2; = p.P1216L on NM_015224.3) | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX15 | c.6751_6753del p.I2251del (on ENST00000256246; = p.I2634del on NM_001350162.2) | In Frame Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- TOP2B | c.424A>T p.N142Y (on ENST00000264331 / NM_001330700.2; = p.N137Y on NM_001068.3) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.4549C>A p.P1517T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); called by muse, mutect2
- CDAN1 | c.160T>C p.L54= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs1324713221; called by muse, mutect2, varscan2
- EGR1 | c.102G>A p.K34= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs368477832, COSV53518271; called by muse, varscan2
- IGHV2-70 | c.30A>C p.L10= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs781292434; called by mutect2, varscan2
- ITGA9 | c.2712C>T p.N904= | Silent (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- MAP4K4 | c.1140G>A p.Q380= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- AC134312.1 | n.234C>T | RNA (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- ACADSB | c.*1932T>A | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ACTR8 | c.*1358G>T | 3'UTR (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- AGBL3 | c.*291T>A | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- AKAP13 | c.478+155C>T | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as rs1567110727; called by muse, mutect2, varscan2
- AP001360.3 | n.464C>T | RNA (SNP) | VAF 11/26 reads (42%) | catalogued as rs954734307; called by muse, mutect2, varscan2
- APOOL | c.*60G>T | 3'UTR (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- ARC | c.*437C>T | 3'UTR (SNP) | VAF 18/37 reads (49%) | catalogued as rs1450243979; called by muse, mutect2, varscan2
- ASGR1 | c.*51C>T | 3'UTR (SNP) | VAF 36/73 reads (49%) | catalogued as rs548074236, COSV99352385; called by muse, mutect2, varscan2
- ASH1L | c.5828+4799G>A | Intron (SNP) | VAF 9/48 reads (19%) | catalogued as rs771331473; called by mutect2, varscan2
- BMP6 | c.*977C>T | 3'UTR (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- BORCS7 | c.*1493G>C | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- CALN1 | c.*3105C>T | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- CCNH | chr5:87393902 G>T | 3'Flank (SNP) | VAF 17/44 reads (39%) | catalogued as rs998291463; called by muse, varscan2
- CDH19 | c.*3714A>T | 3'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- CDH8 | c.*1280A>C | 3'UTR (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*6471C>A | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- DGKB | c.*428C>T | 3'UTR (SNP) | VAF 32/84 reads (38%) | catalogued as rs895579680; called by muse, mutect2, varscan2
- EXT1 | c.*5059A>G | 3'UTR (SNP) | VAF 23/65 reads (35%) | catalogued as rs1055994330; called by muse, mutect2, varscan2
- GLYATL1 | n.14G>A | RNA (SNP) | VAF 14/50 reads (28%) | catalogued as rs967720320; called by muse, mutect2, varscan2
- GPR161 | c.-139+2226G>A | Intron (SNP) | VAF 7/151 reads (5%) | called by muse, mutect2
- HCN4 | c.*1297A>G | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- HTR3B | c.-176C>G | 5'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- INVS | c.273+3978G>A | Intron (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- KAT6A | c.1483-1994G>A | Intron (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- MED12L | chr3:151086614 G>A | 5'Flank (SNP) | VAF 32/71 reads (45%) | catalogued as rs1424858868; called by muse, mutect2, varscan2
- MICAL3 | c.2801+544T>C | Intron (SNP) | VAF 27/72 reads (38%) | called by muse, varscan2
- MICAL3 | c.2801+543C>G | Intron (SNP) | VAF 26/72 reads (36%) | called by muse, varscan2
- MIP | c.*1659A>G | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- MOB3C | c.-51+645G>A | Intron (SNP) | VAF 28/65 reads (43%) | called by muse, varscan2
- MRGPRX10P | n.179G>A | RNA (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- NPNT | c.172+14151A>T | Intron (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*4162C>T | 3'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as rs550644009; called by muse, mutect2, varscan2
- PRPF8 | c.-11-94G>A | Intron (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- PRSS38 | c.*220T>C | 3'UTR (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- PTGS1 | c.*837G>A | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, varscan2
- RAB26 | c.*648G>C | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- RAB32 | c.*179C>A | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, varscan2
- RICTOR | c.4136+285G>T | Intron (SNP) | VAF 33/86 reads (38%) | catalogued as COSV99705792; called by muse, mutect2, varscan2
- RNF144B | c.*2341_*2342insGT | 3'UTR (INS) | VAF 6/38 reads (16%) | catalogued as rs1002017572; called by pindel, varscan2
- RPL38 | c.64+162T>G | Intron (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2
- RTN2 | c.34+192C>G | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2
- SENP7 | c.1837+486T>C | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- SGK1 | c.-12C>A | 5'UTR (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- SNORD116-11 | chr15:25079221 G>A | 3'Flank (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*5771A>C | 3'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- TSC1 | c.*1251C>T | 3'UTR (SNP) | VAF 51/121 reads (42%) | catalogued as rs773490178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WASF2 | c.*2201C>G | 3'UTR (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.*206G>A | 3'UTR (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100602354; called by muse, mutect2, varscan2
